Gene-level copy-number profile of tumor specimen C3L-01836-03 from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 149b061e-2154-4294-9a34-49567ef3952a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01836-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/7765eab0-cece-46af-b176-1d2dd7d2530a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,741; copy number 1: 3,832; copy number 2: 50,068; copy number 3: 902; copy number 4: 42; copy number 5: 254; copy number 6: 1,075; copy number 8: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 2,736 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:10,589,166–10,604,830, 1 gene (within-gene range 0–2): AC007314.1.
- chr3:11,745–86,496,996, 1,314 genes (broad region; genes not listed).
- chr6:68,332,019–170,738,536, 1,420 genes (broad region; genes not listed).
- chr11:2,989,863–2,991,344, 1 gene (within-gene range 0–1): AC131971.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,331 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:107,699,392–108,382,098, 5 genes, copy number 6: AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:113,022,099–181,342,213, 1,321 genes, copy number 5–6 (broad region; genes not listed).
- chr10:133,623,895–133,626,795, 1 gene, copy number 6: FRG2B.
- chr10:133,778,246–133,778,699, 2 genes, copy number 6: RPL23AP60, BX322534.1.
- chr16:90,173,217–90,222,851, 1 gene, copy number 10 (within-gene range 1–10): LINC02193.
- chr21:46,690,764–46,691,226, 1 gene, copy number 8: RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 981. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
